Somatic mutation profile of tumor specimen 0DGOAQ from CCDI case PBBTPR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.4 years (1,589 days).
Specimen 0DGOAQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb380076-683d-4838-9186-ecc15eba4ec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49609e12-496f-4ba7-a4cc-ce0986205a65

The open-access MAF lists 28 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Nonsense Mutation 3, 5'UTR 2, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAR3 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 108/384 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777183149; called by muse, mutect2, varscan2
- CDSN | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 121/434 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as rs953173935; called by muse, mutect2, varscan2
- CHCHD6 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147493885; called by muse, mutect2, varscan2
- CST5 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 121/504 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144164912; called by muse, mutect2, varscan2
- DNASE1L3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 149/638 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs561644406; called by muse, mutect2
- NAIF1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 119/442 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100895692; called by muse, mutect2, varscan2
- PC | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 177/657 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893534714; called by muse, mutect2, varscan2
- PGLYRP2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52992630; called by muse, mutect2
- SMARCB1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 317/590 reads (54%) | catalogued as CM034687, COSV54096035, COSV54099986; called by muse, mutect2, varscan2
- TAF2 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 140/491 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.336); catalogued as COSV65418458; called by muse, mutect2, varscan2
- TMPRSS3 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 209/749 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1251706736; called by muse, mutect2, varscan2
- DNAJB5 | c.72C>G p.Y24* | Nonsense Mutation (SNP) | VAF 96/379 reads (25%) | called by muse, mutect2, varscan2
- GRID2 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 155/560 reads (28%) | called by muse, mutect2, varscan2
- NOVA2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF510 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CRMP1 | c.102C>T p.D34= | Silent (SNP) | VAF 100/622 reads (16%) | catalogued as rs149094396; called by muse, mutect2, varscan2
- FAM120B | c.2199G>A p.T733= | Silent (SNP) | VAF 139/585 reads (24%) | catalogued as rs150094606, COSV99379890; called by muse, mutect2, varscan2
- FAM186A | c.5154G>A p.S1718= | Silent (SNP) | VAF 126/439 reads (29%) | catalogued as rs1480492035, COSV59251109; called by muse, mutect2, varscan2
- MARVELD2 | c.411C>T p.Y137= | Silent (SNP) | VAF 130/535 reads (24%) | catalogued as rs756703445; called by muse, mutect2, varscan2
- MRPL39 | c.963G>A p.R321= | Silent (SNP) | VAF 50/628 reads (8%) | called by muse, mutect2
- NTN3 | c.819C>A p.I273= | Silent (SNP) | VAF 67/400 reads (17%) | called by muse, mutect2, varscan2
- PXDN | c.2691G>A p.V897= | Silent (SNP) | VAF 148/518 reads (29%) | called by muse, mutect2, varscan2
- TCIRG1 | c.2241G>C p.L747= | Silent (SNP) | VAF 107/444 reads (24%) | called by muse, mutect2, varscan2
- AC008806.1 | n.135C>T | RNA (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445633 del CA | 5'Flank (DEL) | VAF 81/306 reads (26%) | called by mutect2, pindel, varscan2
- MSR1 | c.1033+2579A>T | Intron (SNP) | VAF 55/244 reads (23%) | called by muse, mutect2, varscan2
- RUBCNL | c.-28G>A | 5'UTR (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- TRDN | c.-40A>C | 5'UTR (SNP) | VAF 20/417 reads (5%) | called by muse, mutect2
